Surgical pathology report (de-identified scan), TCGA case TCGA-5N-A9KM, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5N-A9KM-01A (Primary Tumor).

Slide of cystectomy with a poorly differentiated urothelial carcinoma involving the posterior and side walls. The features denote a Carcinoma in situ. The tumor infiltrates the prevesical fat layer. Surgical margins are tumor free. Uterus has atrophic Corpus Endometrium without atypic figures. Endo and Ecto cervix is free of dysplasia.

Classification pTNM 2010

Stage: pT4a pN0 (0/16) L0 V0 Pn1

Grade: G3

R-Classification: Local R0

ICD-O: 8120/3

ICD-O-3
Carcinoma, urothelial NOS 8120/3
Site: Bladder NOS C67.9
JW 5/9/14

Source: NCI Genomic Data Commons file 5c1a638e-a102-49f2-b4c0-2b642838f51a (TCGA-5N-A9KM.3DA2EAED-CD7A-4102-9871-74AA445DD4F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).